Surgical pathology report (de-identified scan), TCGA case TCGA-AG-3896, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-3896-01A (Primary Tumor).

Structured brief findings (cito processing) and diagnosis relating to the clinical problem:

This material shows an invasive adenocarcinoma of the colon (rectal carcinoma G2) of moderate differentiation with extensive infiltration of the muscularis, corresponding to pT2, vascular infiltration (corresponding to L1, V1),

it further shows free resection margins with regard to the deep resection margin and the resection margins in the mucosa region, as well as free lymph nodes and a free anastomosis ring.

Tumor classification:

ICDO-DA M 8140/3

G2

pT2 L1, V1, pN0 (0/12)

Source: NCI Genomic Data Commons file 4b64138d-aa25-44cd-a3c6-4e056b6eb902 (TCGA-AG-3896.0FA22AA3-4132-43D9-8FB7-B57060111592.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).